Somatic mutation profile of tumor specimen TCGA-D7-A4YT-01A (aliquot TCGA-D7-A4YT-01A-11D-A25D-08) from TCGA case TCGA-D7-A4YT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 56.8 years (20,742 days).
Specimen TCGA-D7-A4YT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54650077-9bec-4c04-9f06-5a6bad88c308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A4YT-10A (Blood Derived Normal), aliquot TCGA-D7-A4YT-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95594ace-3e04-4262-985a-0e2522082473

The open-access MAF lists 323 somatic variants for this specimen: 236 protein-altering or splice-affecting, 82 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 82, Frame Shift Del 19, Nonsense Mutation 11, Splice Site 8, Frame Shift Ins 6, In Frame Del 5, Intron 4, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- COL18A1 | c.3363del p.G1122Dfs*17 (on ENST00000359759 / NM_130444.3; = p.G887Dfs*17 on NM_030582.4) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs775168204; ClinVar: pathogenic; called by pindel, varscan2
- AADACL2 | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.381); catalogued as COSV62932049; called by muse, mutect2, varscan2
- ABCF1 | c.1846G>C p.D616H (on ENST00000326195 / NM_001025091.2; = p.D578H on NM_001090.3) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV58230430; called by muse, mutect2, varscan2
- ACTC1 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.789); catalogued as rs1224080351, COSV51760957; called by muse, mutect2, varscan2
- ADAD1 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56646741; called by muse, mutect2, varscan2
- ADGRG3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs752087259, COSV59651487; called by muse, mutect2, varscan2
- ADGRG7 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56300397; called by muse, mutect2, varscan2
- AKNAD1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV62202532; called by muse, mutect2, varscan2
- APOL5 | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV50768039; called by muse, mutect2, varscan2
- ARHGAP24 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV67840731; called by muse, mutect2, varscan2
- ARHGAP31 | c.2429C>G p.S810C | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs750659284, COSV51797772; called by muse, mutect2, varscan2
- ARHGAP33 | c.1387A>C p.N463H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50149652; called by muse, mutect2, varscan2
- ARHGAP6 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 227/271 reads (84%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV57301477; called by muse, mutect2, varscan2
- ASIC1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.049); catalogued as COSV57319812; called by muse, mutect2, varscan2
- ATAD2 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV54885507; called by muse, mutect2, varscan2
- ATR | c.6389C>G p.T2130R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV63390879; called by muse, mutect2, varscan2
- ATXN1 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs537102584, COSV55214195; called by muse, mutect2, varscan2
- ATXN7 | c.896C>A p.T299N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as rs1456960662, COSV55755404; called by muse, mutect2, varscan2
- AUTS2 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61425311; called by muse, mutect2, varscan2
- AUTS2 | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.24); catalogued as rs151096425, COSV61425316; called by muse, mutect2, varscan2
- BECN1 | c.859A>G p.N287D | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV59312688; called by muse, mutect2, varscan2
- BOD1L1 | c.2380A>T p.R794W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50047058; called by muse, mutect2, varscan2
- BRPF3 | c.2694G>C p.L898F | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV60209312; called by muse, mutect2, varscan2
- C1orf100 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV57373854; called by muse, mutect2, varscan2
- C1orf127 | c.1892G>C p.G631A | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV65438652; called by muse, mutect2, varscan2
- C6orf89 | c.506T>A p.L169Q (on ENST00000373685; = p.L176Q on NM_152734.4) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV62103045; called by muse, mutect2, varscan2
- CABYR | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV59112344; called by muse, mutect2, varscan2
- CACNB3 | c.1346G>C p.S449T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.018); catalogued as COSV56400299; called by muse, mutect2, varscan2
- CAMSAP1 | c.3719A>C p.D1240A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as COSV56727473; called by muse, mutect2, varscan2
- CCDC9 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV55722383; called by muse, mutect2
- CD2AP | c.1620C>G p.C540W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV63762595; called by muse, mutect2, varscan2
- CDC37L1 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67866273; called by muse, mutect2, varscan2
- CDC42SE1 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV61785836; called by muse, mutect2, varscan2
- CDC6 | c.1084-1G>T p.X362_splice | Splice Site (SNP) | VAF 11/342 reads (3%) | catalogued as COSV52931488, COSV99266484; called by muse, mutect2
- CEP70 | c.723A>C p.E241D | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as COSV53877827; called by muse, mutect2, varscan2
- CERS5 | c.146C>G p.S49W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV58190166; called by muse, mutect2
- CHTF18 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV50102083; called by muse, mutect2, varscan2
- CNST | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV63620991; called by muse, mutect2, varscan2
- COL6A6 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62034777; called by muse, mutect2, varscan2
- COL9A2 | c.1549-1G>C p.X517_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV65623830; called by muse, mutect2, varscan2
- COL9A2 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65623838; called by muse, mutect2, varscan2
- COQ8A | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV62018442; called by muse, mutect2
- CSNK1A1 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV55797480; called by muse, mutect2, varscan2
- CYLC1 | c.1458G>A p.M486I | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61414198; called by muse, mutect2, varscan2
- CYP51A1 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 37/144 reads (26%) | catalogued as rs981295706, COSV50153640; called by muse, mutect2, varscan2
- CYTH4 | c.114T>A p.D38E | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV50635308; called by muse, mutect2, varscan2
- DOP1B | c.3602A>T p.E1201V | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV67695506; called by muse, mutect2, varscan2
- DPP8 | c.547G>A p.G183S (on ENST00000341861 / NM_001320875.2; = p.G167S on NM_017743.6) | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as rs753995054, COSV55682468; called by muse, mutect2, varscan2
- DSTYK | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV100904528, COSV65688173; called by mutect2, varscan2
- DXO | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV61714838; called by muse, mutect2, varscan2
- DYSF | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV50537941; called by muse, mutect2, varscan2
- ENGASE | c.863A>T p.Q288L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV56137381; called by muse, mutect2, varscan2
- EPHA10 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 96/151 reads (64%) | SIFT tolerated (0.45); PolyPhen benign (0.419); catalogued as COSV57626666; called by muse, mutect2, varscan2
- ESF1 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV52523699; called by muse, mutect2, varscan2
- FAM118B | c.110C>G p.T37S | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV64157367, COSV64157585; called by muse, mutect2, varscan2
- FAM86B1 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV58670273; called by mutect2, varscan2
- FAT3 | c.175A>T p.R59W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53162191; called by muse, mutect2, varscan2
- FBN1 | c.1876G>C p.G626R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161871, COSV57327758; called by muse, mutect2, varscan2
- FBXO44 | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 118/161 reads (73%) | catalogued as COSV52355277; called by muse, mutect2, varscan2
- FCN2 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV52478341; called by muse, mutect2, varscan2
- FER | c.2252G>C p.W751S | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55299176; called by muse, varscan2
- FOXL2 | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1409604799, COSV57729885; called by muse, mutect2, varscan2
- G6PC2 | c.489T>A p.S163R | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.343); catalogued as COSV56373326; called by muse, mutect2, varscan2
- GABRB1 | c.1154C>G p.T385R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.63); catalogued as COSV54986758, COSV54988972, COSV54996341; called by muse, mutect2, varscan2
- GALNTL5 | c.1093C>A p.Q365K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV67180971; called by muse, mutect2, varscan2
- GAST | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 183/1042 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.011); catalogued as rs1555585725, COSV61475804; called by muse, mutect2, varscan2
- GATA1 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64961894; called by muse, mutect2, varscan2
- GIP | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100656965, COSV62467056, COSV62467669; called by muse, mutect2, varscan2
- GOLPH3 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1230145949, COSV54062315; called by muse, mutect2, varscan2
- GPAM | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV62082334; called by muse, mutect2, varscan2
- GPRIN2 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs781784858, COSV65402374; called by muse, mutect2, varscan2
- GRAMD1A | c.1254C>G p.H418Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV58768668; called by muse, mutect2, varscan2
- GRIK5 | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53478685; called by muse, mutect2, varscan2
- GRIN2A | c.2533C>G p.L845V | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV58053238; called by muse, mutect2, varscan2
- GRIN3A | c.1621C>A p.Q541K | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV62457355; called by muse, mutect2, varscan2
- HERC5 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.163); catalogued as COSV52043768; called by muse, mutect2, varscan2
- HSPA4L | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.473); catalogued as COSV56547951; called by muse, mutect2, varscan2
- HTR2A | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66328236; called by muse, mutect2, varscan2
- IFT81 | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99655836; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 75/559 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs759020817; called by muse, mutect2, varscan2
- IL17RA | c.139-2A>T p.X47_splice | Splice Site (SNP) | VAF 38/106 reads (36%) | catalogued as COSV60055736; called by muse, mutect2, varscan2
- IL1RAPL1 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV56282633, COSV56292448; called by muse, mutect2, varscan2
- INHBA | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54220650; called by muse, mutect2, varscan2
- INPP4B | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs762779783, COSV53741108; called by muse, mutect2, varscan2
- INTU | c.2488C>T p.Q830* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as COSV100081191, COSV58874099; called by muse, mutect2, varscan2
- IQCA1 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770359937, COSV54502847, COSV54510846; called by muse, mutect2, varscan2
- ISL1 | c.822C>A p.D274E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.029); catalogued as COSV100045194; called by muse, varscan2
- JHY | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1008104966, COSV56220426, COSV56221804; called by muse, mutect2
- KAT2A | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs782708792, COSV56792581; called by muse, mutect2, varscan2
- KATNBL1 | c.439-1G>C p.X147_splice | Splice Site (SNP) | VAF 19/48 reads (40%) | catalogued as rs1567516927, COSV56625211; called by muse, mutect2, varscan2
- KCNG4 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs780189137, COSV100376935, COSV57585636; called by muse, mutect2, varscan2
- KCNJ3 | c.782A>C p.Q261P | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54542959; called by muse, mutect2, varscan2
- KIAA0586 | c.3232C>T p.P1078S (on ENST00000619416 / NM_001244190.2; = p.P1017S on NM_014749.5) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs77810875, COSV54181114; called by muse, mutect2, varscan2
- KIAA1841 | c.812A>C p.N271T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.532); catalogued as COSV54378096; called by muse, mutect2, varscan2
- KMT2C | c.13059A>C p.R4353S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV51489951; called by muse, mutect2, varscan2
- KPRP | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 99/205 reads (48%) | catalogued as rs1165264771, COSV100908797, COSV64222757; called by muse, mutect2, varscan2
- LANCL1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs371433604, COSV52064155; called by muse, mutect2, varscan2
- LCT | c.2992G>T p.D998Y | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51547069; called by muse, mutect2, varscan2
- LGR6 | c.2420C>A p.A807D (on ENST00000367278 / NM_001017403.1; = p.A755D on NM_021636.3) | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55164825, COSV99706425; called by muse, mutect2, varscan2
- LHX2 | c.1004A>T p.K335M | Missense Mutation (SNP) | VAF 68/91 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV65318987; called by muse, mutect2, varscan2
- LMCD1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV50091375; called by muse, mutect2, varscan2
- LTBP4 | c.1751G>C p.R584P (on ENST00000308370 / NM_001042544.1; = p.R547P on NM_003573.2) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV52588831; called by muse, mutect2, varscan2
- LY9 | c.1087C>G p.P363A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54436988; called by muse, mutect2, varscan2
- MAN1B1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV65378499; called by muse, mutect2
- MAPKAP1 | c.1205T>C p.L402P (on ENST00000265960 / NM_001006617.3; = p.L366P on NM_024117.3) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56373221; called by muse, mutect2, varscan2
- MICALL1 | c.1465+2T>C p.X489_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as COSV53242947; called by muse, mutect2, varscan2
- MIPOL1 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV59391661; called by muse, mutect2, varscan2
- MNDA | c.515A>T p.H172L | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as COSV63741872; called by muse, mutect2, varscan2
- NDUFB8 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54512484; called by muse, mutect2, varscan2
- NLRP4 | c.2666C>T p.T889M | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as rs753705551, COSV56712567; called by muse, mutect2, varscan2
- NUDCD2 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57085513; called by muse, mutect2, varscan2
- OGDHL | c.2022C>A p.H674Q | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65104195; called by muse, mutect2, varscan2
- OPRL1 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61092635; called by muse, mutect2, varscan2
- OTOF | c.2597C>T p.P866L (on ENST00000272371 / NM_194248.3; = p.P119L on NM_004802.4) | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV55515910; called by muse, mutect2, varscan2
- PCDHGA2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as rs746073058, COSV54013789; called by muse, mutect2, varscan2
- PCNX2 | c.5197C>A p.P1733T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50862488; called by muse, mutect2, varscan2
- PDLIM4 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53805100, COSV53805161; called by muse, mutect2, varscan2
- PHF19 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65878912; called by muse, varscan2
- PHF19 | c.1526T>A p.V509D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV65878916; called by muse, varscan2
- PLA2G2E | c.81G>T p.M27I | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV64290882; called by muse, mutect2, varscan2
- POGK | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV63312256; called by muse, mutect2, varscan2
- POLB | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV55348348; called by muse, mutect2, varscan2
- POSTN | c.1649A>T p.E550V | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV65714279; called by muse, mutect2, varscan2
- PPM1N | c.784C>A p.R262S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs375570529, COSV55595357; called by muse, mutect2, varscan2
- PPP1R12A | c.988A>C p.N330H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); catalogued as COSV54113143; called by muse, mutect2
- PPRC1 | c.902G>C p.S301T | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV53387893; called by muse, mutect2, varscan2
- PRKCG | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1365634675, COSV54731908; called by muse, mutect2, varscan2
- PRLR | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51499525; called by muse, mutect2, varscan2
- PRRC2C | c.506G>A p.G169E (on ENST00000367742; = p.G167E on NM_015172.4) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58911594; called by muse, mutect2, varscan2
- PRUNE1 | c.1339A>C p.T447P | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV54848546; called by muse, mutect2, varscan2
- PTGR1 | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.236); catalogued as COSV53030506; called by muse, mutect2, varscan2
- PTPRS | c.3927A>C p.K1309N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV53633958; called by muse, mutect2, varscan2
- PTPRT | c.2590C>A p.Q864K | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV62011444; called by muse, mutect2, varscan2
- RAD51D | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60005930; called by muse, mutect2, varscan2
- RAI1 | c.2056C>G p.L686V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.056); catalogued as COSV55397724; called by muse, mutect2, varscan2
- RALGAPB | c.2812C>A p.P938T | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV53442987; called by muse, mutect2, varscan2
- RANBP6 | c.2504C>G p.S835C | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV52391083; called by muse, mutect2, varscan2
- RFX5 | c.1784T>A p.L595* | Nonsense Mutation (SNP) | VAF 113/191 reads (59%) | catalogued as COSV51841146; called by muse, mutect2, varscan2
- RGS4 | c.470T>C p.F157S | Missense Mutation (SNP) | VAF 161/632 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV63358041; called by muse, mutect2, varscan2
- RNF8 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV57722115; called by muse, mutect2, varscan2
- RRS1 | c.974G>C p.G325A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV52558461; called by muse, mutect2, varscan2
- RUNDC3B | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV56696376; called by muse, mutect2, varscan2
- RUSC1 | c.2422T>C p.S808P (on ENST00000368352 / NM_001105203.2; = p.S339P on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/474 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52742059; called by muse, mutect2
- SACS | c.5720G>A p.R1907Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1235580034, COSV66538120; called by muse, mutect2, varscan2
- SAMD15 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV53630344; called by muse, mutect2, varscan2
- SAMD3 | c.1335C>G p.C445W | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV62388425, COSV62390229; called by muse, mutect2, varscan2
- SBNO2 | c.3040G>A p.G1014S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as COSV100684689, COSV62322954; called by muse, mutect2, varscan2
- SCN3A | c.359T>G p.I120S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as COSV51821234; called by muse, varscan2
- SCN4A | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71128706; called by muse, varscan2
- SCN8A | c.5496G>A p.M1832I | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61991195; called by muse, mutect2, varscan2
- SELP | c.2493A>C p.*831Yext*7 | Nonstop Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV55256976; called by muse, varscan2
- SELP | c.2459T>G p.V820G | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55257004, COSV99739288; called by muse, varscan2
- SENP3 | c.988A>C p.S330R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53437583; called by muse, mutect2, varscan2
- SEPTIN1 | c.433G>C p.D145H (on ENST00000321367; = p.D98H on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58443413; called by muse, mutect2, varscan2
- SLC35F1 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as rs759102731, COSV64505555; called by muse, mutect2, varscan2
- SLC4A11 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs769018264, COSV66263565; called by muse, mutect2, varscan2
- SLITRK1 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV65677181; called by muse, mutect2, varscan2
- SORCS3 | c.2959C>A p.L987I | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV63797390, COSV63797871; called by muse, mutect2, varscan2
- SPINDOC | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53693637; called by muse, mutect2, varscan2
- SPTBN4 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as rs145007629; called by muse, mutect2, varscan2
- SSH1 | c.2902A>T p.T968S | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58459385; called by muse, mutect2, varscan2
- ST18 | c.1902C>A p.N634K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV52506255; called by muse, mutect2, varscan2
- STK3 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69225618, COSV69226334; called by muse, mutect2, varscan2
- SULT1B1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV60209109; called by muse, mutect2, varscan2
- SYT6 | c.1271T>G p.L424R (on ENST00000610222 / NM_001366225.1; = p.L339R on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65775707; called by muse, mutect2, varscan2
- TAS2R38 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV71885943; called by muse, mutect2, varscan2
- TBC1D21 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55996458; called by muse, mutect2, varscan2
- TBXT | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV51619626; called by muse, mutect2, varscan2
- TCHP | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV57166366; called by muse, mutect2, varscan2
- TECPR1 | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101130431, COSV65784871, COSV65785600; called by muse, mutect2, varscan2
- TEP1 | c.6033C>A p.F2011L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52998459; called by muse, mutect2, varscan2
- TG | c.5859G>T p.K1953N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV55090939; called by muse, mutect2
- TGFBR2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55449689; called by muse, mutect2, varscan2
- TMED8 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53627738; called by muse, mutect2, varscan2
- TMED9 | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50354892; called by muse, mutect2, varscan2
- TMEM190 | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV52582385; called by muse, mutect2, varscan2
- TNFAIP3 | c.45G>T p.M15I | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV52801669; called by muse, mutect2, varscan2
- TNK2 | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV57374634; called by muse, mutect2
- TRAPPC13 | c.464G>C p.G155A | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV51560015; called by muse, mutect2
- TRAPPC4 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57723681; called by muse, mutect2, varscan2
- TRPM1 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373261110; called by muse, mutect2, varscan2
- TTLL3 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV59615481; called by muse, mutect2, varscan2
- TTN | c.9538T>C p.Y3180H (on ENST00000591111; = p.Y3134H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/84 reads (6%) | PolyPhen possibly damaging (0.814); catalogued as rs1553987902, COSV60284957; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.8186A>C p.E2729A (on ENST00000591111; = p.E2683A on NM_003319.4) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | PolyPhen probably damaging (0.995); catalogued as COSV60284996; called by muse, mutect2, varscan2
- UBAC1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 45/304 reads (15%) | catalogued as rs1274626949, COSV65614556; called by muse, mutect2, varscan2
- UGT1A4 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV59396483; called by muse, varscan2
- UGT2B4 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs1314997496, COSV59316881; called by muse, mutect2, varscan2
- UNC80 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99778871; called by muse, mutect2, varscan2
- USP28 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV50182771; called by muse, mutect2, varscan2
- VPS8 | c.1039G>T p.D347Y (on ENST00000625842 / NM_001349294.1; = p.D345Y on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs754358248, COSV54994508; called by muse, mutect2, varscan2
- VRTN | c.1950G>T p.K650N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1376566134, COSV56443200; called by muse, mutect2, varscan2
- WHAMM | c.1816A>C p.S606R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV54498871; called by muse, mutect2, varscan2
- XYLT1 | c.1364A>T p.N455I | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV54494354; called by muse, mutect2, varscan2
- ZBED9 | c.1405A>T p.S469C | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.945); catalogued as COSV71729720; called by muse, mutect2, varscan2
- ZBTB1 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62438900; called by muse, mutect2, varscan2
- ZC3H3 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as COSV52794125; called by muse, mutect2, varscan2
- ZNF230 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV71273584, COSV71273653; called by muse, mutect2, varscan2
- ZNF233 | c.1673A>G p.H558R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61934496; called by muse, mutect2, varscan2
- ZNF296 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55517335; called by muse, mutect2, varscan2
- ZNF638 | c.4955A>T p.D1652V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV52495019; called by muse, mutect2, varscan2
- ZNF677 | c.793T>C p.C265R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs141599719; called by muse, mutect2, varscan2
- ZNF711 | c.1950G>C p.R650S | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1385831814, COSV52154884, COSV52158137; called by muse, mutect2, varscan2
- ARID1A | c.4005-5_4035del p.X1335_splice | Splice Site (DEL) | VAF 77/189 reads (41%) | called by mutect2, pindel
- CC2D2B | c.262_301del p.L88Ifs*15 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- CYB5D2 | c.412_436del p.Y138Rfs*3 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel
- FAM72A | c.411_424del p.E137Dfs*8 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- FAT4 | c.57_66del p.V21Sfs*38 | Frame Shift Del (DEL) | VAF 19/217 reads (9%) | called by mutect2, pindel
- GCN1 | c.4626_4652del p.K1542_H1551delinsN | In Frame Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- HDLBP | c.1817dup p.I607Dfs*3 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- INHBC | c.207_208del p.R69Sfs*28 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by pindel, varscan2
- KAT2A | c.728_732del p.F243Sfs*22 | Frame Shift Del (DEL) | VAF 13/125 reads (10%) | called by mutect2, pindel
- KIAA0100 | c.3192_3198del p.L1064Ffs*42 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- LRRK2 | c.572-2_614del p.X191_splice | Splice Site (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- LY6G6C | c.339dup p.T114Yfs*53 | Frame Shift Ins (INS) | VAF 18/152 reads (12%) | called by pindel, varscan2
- MACF1 | c.9084_9100del p.E3029* | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel
- MED13 | c.4759_4788del p.Q1587_G1596del | In Frame Del (DEL) | VAF 22/138 reads (16%) | called by mutect2, pindel
- MROH2B | c.2361_2361+1insATTG p.D788Ifs*5 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.6782_6801+14del p.X2261_splice (on ENST00000357337; = p.X2299_splice on NM_015057.5) | Splice Site (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel
- MYT1L | c.1466dup p.P490Afs*4 | Frame Shift Ins (INS) | VAF 28/49 reads (57%) | called by mutect2, pindel, varscan2
- NACC2 | c.742A>G p.S248G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- NUP153 | c.514_531del p.S172_D177del | In Frame Del (DEL) | VAF 24/83 reads (29%) | called by mutect2, pindel, varscan2
- OR11H1 | c.820dup p.M274Nfs*5 | Frame Shift Ins (INS) | VAF 41/182 reads (23%) | called by mutect2, pindel, varscan2
- PAPSS2 | c.1110_1126del p.D370Efs*6 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- PCDH7 | c.1077_1089del p.L360Pfs*15 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by pindel, varscan2
- PLCE1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- RCN1 | c.820_838del p.L274Mfs*21 | Frame Shift Del (DEL) | VAF 49/105 reads (47%) | called by pindel, varscan2
- RNF43 | c.498_520del p.N167Vfs*13 | Frame Shift Del (DEL) | VAF 43/87 reads (49%) | called by mutect2, pindel, varscan2
- RSPH1 | c.40_47del p.E14Yfs*5 | Frame Shift Del (DEL) | VAF 41/67 reads (61%) | called by mutect2, pindel, varscan2
- SLC6A6 | c.1820_1848del p.A607Gfs*26 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel
- TRPS1 | c.1784_1792del p.C595_L597del (on ENST00000220888 / NM_001330599.2; = p.C608_L610del on NM_014112.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 37/82 reads (45%) | called by mutect2, pindel, varscan2
- TTN | c.48426_48464del p.N16143_I16155del (on ENST00000591111; = p.N8719_I8731del on NM_003319.4) | In Frame Del (DEL) | VAF 32/120 reads (27%) | called by mutect2, pindel
- UGT1A4 | c.453_465del p.D152Sfs*25 | Frame Shift Del (DEL) | VAF 48/196 reads (24%) | called by pindel, varscan2
- VARS1 | c.270_294del p.R91Gfs*9 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel
- ZNF296 | c.178_193del p.G60Nfs*30 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- ZNF44 | c.1190_1196del p.P397Qfs*11 (on ENST00000356109 / NM_001164276.2; = p.P349Qfs*11 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/130 reads (32%) | called by mutect2, pindel, varscan2
- ABAT | c.1257G>A p.L419= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1192973748, COSV51627272; called by muse, mutect2
- ACP5 | c.249C>T p.D83= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV54537222; called by muse, mutect2
- ACTN4 | c.1128G>A p.E376= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV53149631; called by muse, mutect2, varscan2
- AKAP12 | c.1098C>T p.H366= | Silent (SNP) | VAF 62/200 reads (31%) | catalogued as rs752192182, COSV53578322; called by muse, mutect2, varscan2
- ALMS1 | c.10152A>C p.T3384= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as COSV52519638; called by muse, mutect2, varscan2
- ANKRD6 | c.1125C>T p.N375= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs954642296, COSV60235682; called by muse, mutect2, varscan2
- ARHGEF18 | c.1497G>T p.V499= (on ENST00000359920 / NM_001130955.2; = p.V395= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV100149384, COSV60473192; called by muse, mutect2, varscan2
- ASB1 | c.468G>T p.R156= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV52828038; called by muse, mutect2, varscan2
- ASTL | c.1239A>G p.P413= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as COSV60904830, COSV60905167; called by muse, mutect2, varscan2
- ATP13A5 | c.2277C>T p.T759= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as COSV60873939; called by muse, mutect2, varscan2
- C15orf39 | c.2199G>A p.Q733= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV62297970; called by muse, mutect2
- C1orf87 | c.1542G>A p.L514= | Silent (SNP) | VAF 125/217 reads (58%) | catalogued as COSV64598405; called by muse, mutect2, varscan2
- CBFA2T2 | c.1311T>C p.F437= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV60801649; called by muse, mutect2, varscan2
- CDH18 | c.606C>T p.L202= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs201475677, COSV56901523; called by muse, mutect2, varscan2
- CERCAM | c.738C>A p.I246= | Silent (SNP) | VAF 79/199 reads (40%) | catalogued as rs780908107, COSV100864062, COSV65711711; called by muse, varscan2
- CGNL1 | c.3768C>T p.D1256= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV55573813; called by muse, mutect2
- CSF3R | c.696G>A p.L232= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV58970837; called by muse, mutect2, varscan2
- CSMD2 | c.1623C>T p.D541= | Silent (SNP) | VAF 81/103 reads (79%) | catalogued as rs778920929, COSV53952243, COSV53966386; called by muse, mutect2
- CYP24A1 | c.1302G>A p.Q434= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV53776276; called by muse, mutect2, varscan2
- DNAJC6 | c.1443C>A p.P481= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV54780408; called by muse, mutect2, varscan2
- DSCAML1 | c.3300G>T p.V1100= (on ENST00000321322; = p.V1040= on NM_020693.4) | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV58400722; called by muse, mutect2, varscan2
- DTL | c.561A>G p.G187= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV65342229; called by muse, mutect2, varscan2
- DUS1L | c.543G>A p.Q181= | Silent (SNP) | VAF 121/156 reads (78%) | catalogued as COSV57648046, COSV57651082; called by muse, mutect2, varscan2
- EHD2 | c.1128G>A p.P376= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs781623704, COSV54410504; called by muse, mutect2, varscan2
- EIF3F | c.336T>G p.G112= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV59143213; called by muse, mutect2, varscan2
- FOXG1 | c.1329G>A p.T443= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV57398962; called by muse, mutect2, varscan2
- GAL3ST4 | c.1185G>A p.E395= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV57587914; called by muse, mutect2
- GALR1 | c.264C>T p.C88= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as COSV55318685; called by muse, mutect2, varscan2
- GLB1L2 | c.1233G>A p.K411= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as COSV60280287; called by muse, mutect2, varscan2
- GPNMB | c.1362G>C p.V454= (on ENST00000381990 / NM_001005340.2; = p.V442= on NM_002510.3) | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV51698350, COSV51700546; called by muse, mutect2, varscan2
- GRIP2 | c.2928C>T p.D976= (on ENST00000619221; = p.D879= on NM_001080423.4) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs750027466, COSV56124089; called by muse, mutect2, varscan2
- GSK3A | c.1137C>T p.L379= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs201590175, COSV55900593; called by muse, mutect2, varscan2
- GTF3C5 | c.1344G>A p.R448= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as COSV59601627; called by muse, mutect2
- HOXC9 | c.69C>T p.L23= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV57717271; called by muse, mutect2, varscan2
- HOXD3 | c.1083C>T p.N361= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV50884705; called by muse, mutect2, varscan2
- IGF1R | c.3909C>T p.V1303= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV51357705; called by muse, mutect2, varscan2
- IL17RE | c.387T>A p.R129= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as COSV55970414; called by muse, mutect2, varscan2
- IRGC | c.1029C>G p.V343= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV54985841; called by muse, mutect2, varscan2
- KLF1 | c.153C>A p.L51= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV53435928; called by muse, mutect2, varscan2
- KRTAP4-2 | c.111C>A p.R37= | Silent (SNP) | VAF 33/242 reads (14%) | catalogued as COSV66658165, COSV66659058; called by muse, mutect2, varscan2
- LAPTM5 | c.249C>T p.G83= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs545456726, COSV53854264; called by muse, mutect2, varscan2
- LUC7L3 | c.192A>G p.E64= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as COSV53589040; called by muse, mutect2, varscan2
- MAS1 | c.831T>A p.P277= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as COSV53122057; called by muse, mutect2, varscan2
- MEX3B | c.1140C>T p.F380= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV61663434; called by muse, mutect2, varscan2
- MFAP5 | c.117A>C p.P39= | Silent (SNP) | VAF 53/87 reads (61%) | catalogued as COSV63946163; called by muse, mutect2, varscan2
- MRC2 | c.3189C>G p.P1063= | Silent (SNP) | VAF 63/151 reads (42%) | catalogued as COSV57643602; called by muse, mutect2, varscan2
- MTR | c.2355C>T p.H785= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs761121279, COSV63964346; called by muse, mutect2, varscan2
- NADK | c.147C>G p.A49= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV58276018; called by muse, mutect2, varscan2
- NEBL | c.2457T>G p.A819= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV65805278; called by muse, mutect2
- NLRP3 | c.2511C>A p.L837= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV60229942; called by muse, mutect2, varscan2
- NOD1 | c.1431C>G p.V477= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV56114402; called by muse, mutect2, varscan2
- OR10K2 | c.120C>A p.G40= | Silent (SNP) | VAF 91/164 reads (55%) | catalogued as COSV59222462; called by muse, mutect2, varscan2
- OR4F15 | c.246T>C p.I82= | Silent (SNP) | VAF 189/268 reads (71%) | catalogued as COSV59970075; called by muse, mutect2, varscan2
- OR6K2 | c.582C>T p.I194= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as rs868026666, COSV62743111; called by muse, mutect2, varscan2
- PCNT | c.3057G>A p.L1019= | Silent (SNP) | VAF 53/88 reads (60%) | catalogued as COSV64032122; called by muse, mutect2, varscan2
- PGK1 | c.921A>T p.I307= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV64832590; called by muse, mutect2, varscan2
- PINK1 | c.531A>G p.T177= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1263856381, COSV58632615; called by muse, mutect2, varscan2
- PNPLA7 | c.622C>T p.L208= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53005314; called by muse, mutect2, varscan2
- PTN | c.48C>A p.A16= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV61968853; called by muse, mutect2, varscan2
- PTPRN2 | c.2625G>T p.L875= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101153286; called by muse, mutect2, varscan2
- RAB3A | c.321G>A p.E107= | Silent (SNP) | VAF 56/120 reads (47%) | catalogued as COSV55853649; called by muse, mutect2, varscan2
- REPIN1 | c.397C>T p.L133= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs1297833979, COSV68292853; called by muse, mutect2, varscan2
- RTRAF | c.645A>G p.L215= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV53501615; called by muse, mutect2, varscan2
- SFRP4 | c.1023A>G p.T341= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as COSV71412639; called by muse, mutect2, varscan2
- SH3GL2 | c.897C>T p.Y299= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs143422821; called by muse, mutect2, varscan2
- SLC25A23 | c.1140G>A p.L380= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV51195584; called by muse, mutect2, varscan2
- SMG6 | c.3055C>T p.L1019= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs1406360823, COSV53973861; called by muse, mutect2, varscan2
- SNX27 | c.831G>C p.L277= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV64327314; called by muse, mutect2, varscan2
- SPEG | c.7896C>A p.I2632= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as COSV56667030, COSV56677964; called by muse, mutect2, varscan2
- SPTB | c.660C>T p.I220= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV101071996, COSV67634542; called by muse, mutect2, varscan2
- STXBP2 | c.1386G>A p.P462= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs778481780, COSV55405171; called by muse, mutect2, varscan2
- SYT1 | c.693T>C p.D231= | Silent (SNP) | VAF 69/112 reads (62%) | catalogued as COSV54069107; called by muse, mutect2, varscan2
- TCF7L1 | c.1766A>G p.*589= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV56402426; called by muse, mutect2, varscan2
- TCHH | c.57C>T p.V19= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV64277243; called by muse, mutect2, varscan2
- TCHHL1 | c.798A>G p.K266= | Silent (SNP) | VAF 85/283 reads (30%) | catalogued as rs1235911644, COSV64284880; called by muse, mutect2, varscan2
- TLN2 | c.4053C>G p.L1351= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV60894515; called by muse, mutect2, varscan2
- USP13 | c.1392C>T p.I464= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs756032614, COSV55868578; called by muse, mutect2, varscan2
- VPS54 | c.2202C>T p.V734= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs374339034, COSV55444370; called by muse, mutect2, varscan2
- WDR13 | c.891G>A p.K297= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV54333281; called by muse, mutect2, varscan2
- YME1L1 | c.1239G>C p.V413= (on ENST00000326799 / NM_139312.3; = p.V356= on NM_014263.4) | Silent (SNP) | VAF 60/191 reads (31%) | catalogued as COSV58761186; called by muse, mutect2, varscan2
- ZHX2 | c.2481C>T p.S827= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs751321473, COSV58716323; called by muse, mutect2, varscan2
- ZSCAN4 | c.654C>T p.S218= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV56592235; called by muse, mutect2, varscan2
- IL22RA1 | c.*1G>C | 3'UTR (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99582853; called by muse, mutect2, varscan2
- NALCN | c.2193-5255_2193-5251del | Intron (DEL) | VAF 11/23 reads (48%) | called by mutect2, pindel, varscan2
- PTGER3 | c.*24-12959A>T | Intron (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2
- TFPI | c.628+5397_628+5427del | Intron (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel
- USH1C | c.1284+6921G>C | Intron (SNP) | VAF 3/49 reads (6%) | catalogued as COSV50015572; called by muse, mutect2
